Somatic mutation profile of tumor specimen C3N-00871-01 (aliquot CPT0094420010) from CPTAC case C3N-00871, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.8 years (21,468 days).
Specimen C3N-00871-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cd5236a-3c45-47c1-b8c3-08bd420f7d9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00871-31 (Blood Derived Normal), aliquot CPT0094480008; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a393746c-f83f-411b-aa9b-13bc8a995f6b

The open-access MAF lists 146 somatic variants for this specimen: 99 protein-altering or splice-affecting, 33 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 33, Intron 7, 3'UTR 3, Splice Region 2, Nonsense Mutation 2, 3'Flank 2, Frame Shift Ins 2, Splice Site 1, RNA 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 152/258 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs879254249, COSV52676020, COSV52700231, COSV52728094, COSV52766542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACKR1 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT tolerated (0.6); PolyPhen probably damaging (1); catalogued as COSV63674629; called by muse, mutect2, varscan2
- ALCAM | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV60247773; called by mutect2, varscan2
- AMFR | c.1528A>G p.I510V | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV51924300; called by muse, mutect2, varscan2
- ATP1A4 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953626229; called by muse, mutect2, varscan2
- CCSER1 | c.1452A>C p.E484D | Missense Mutation (SNP) | VAF 79/291 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs890209048; called by muse, mutect2, varscan2
- CCSER2 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV56507500, COSV56510013; called by muse, varscan2
- COL19A1 | c.3208G>A p.D1070N | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs776295411; called by muse, mutect2, varscan2
- COL28A1 | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 103/256 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs761588485; called by muse, mutect2, varscan2
- CRACDL | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.268); catalogued as rs779437146, COSV101194122; called by muse, mutect2, varscan2
- CRP | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs376890049; called by muse, mutect2, varscan2
- CSHL1 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 120/464 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as rs1426916016; called by muse, mutect2, varscan2
- CSMD2 | c.9635C>T p.T3212M | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755663747, COSV99590248; called by muse, mutect2, varscan2
- CYHR1 | c.93+3G>A | Splice Region (SNP) | VAF 43/200 reads (22%) | catalogued as COSV56761989; called by muse, mutect2, varscan2
- EIF3E | c.18G>C p.L6F | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55203932; called by muse, mutect2, varscan2
- FLG | c.10124G>A p.R3375Q | Missense Mutation (SNP) | VAF 128/484 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as rs551056294, COSV64250419; called by muse, mutect2, varscan2
- FNDC1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs756842140, COSV51932856; called by muse, mutect2, varscan2
- GAS2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53406893; called by muse, mutect2, varscan2
- GJA10 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.022); catalogued as COSV65355107; called by muse, mutect2, varscan2
- GRAMD4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs950568969; called by muse, mutect2, varscan2
- GTF2IRD1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs587756708; called by muse, mutect2, varscan2
- NOL4 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781396096; called by muse, mutect2, varscan2
- NUCB1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs886157097, COSV54387757; called by muse, mutect2, varscan2
- NWD2 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs368553028; called by muse, mutect2, varscan2
- PCDHGA5 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); catalogued as COSV54003429; called by muse, mutect2, varscan2
- PLEKHG2 | c.3989C>A p.A1330D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs771586422, COSV52677991; called by mutect2, varscan2
- SCFD2 | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV101189234; called by muse, mutect2, varscan2
- SNRPB | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV100293464; called by muse, mutect2, varscan2
- SSBP4 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1196155925; called by muse, mutect2, varscan2
- TRAF3 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 114/370 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs137916856; called by muse, mutect2, varscan2
- VWA3B | c.3346A>T p.I1116F | Missense Mutation (SNP) | VAF 62/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs747497324; called by muse, mutect2, varscan2
- WDR44 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140354850, COSV54164384; called by muse, mutect2, varscan2
- WFIKKN1 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as rs757725451, COSV50193492; called by mutect2, varscan2
- ZAP70 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1177191144; called by muse, mutect2, varscan2
- ZNF142 | c.2305C>T p.R769C (on ENST00000411696 / NM_001379660.1; = p.R569C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs751369459, COSV68743104; called by muse, mutect2, varscan2
- ADCY8 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 70/335 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ALG9 | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 241/415 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ANKRD12 | c.1664C>T p.S555L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- AP000812.4 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATN1 | c.1110del p.M371* | Frame Shift Del (DEL) | VAF 62/267 reads (23%) | called by mutect2, pindel, varscan2
- BNIP3 | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1orf35 | c.375-2A>T p.X125_splice | Splice Site (SNP) | VAF 137/305 reads (45%) | called by muse, mutect2, varscan2
- CAGE1 | c.1609A>T p.I537F (on ENST00000512086; = p.I401F on NM_205864.3) | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CASC3 | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CNTNAP4 | c.1203G>A p.W401* | Nonsense Mutation (SNP) | VAF 89/210 reads (42%) | called by muse, mutect2, varscan2
- CRIPT | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CTNNA2 | c.443G>C p.R148T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EBF4 | c.1136dup p.L379Ffs*12 (on ENST00000609451; = p.L375Ffs*12 on NM_001110514.1) | Frame Shift Ins (INS) | VAF 55/236 reads (23%) | called by mutect2, pindel, varscan2
- EBLN2 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- ELMO3 | c.1956G>A p.M652I (on ENST00000652269; = p.M599I on NM_024712.5) | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPM2AIP1 | c.1343A>G p.N448S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT1 | c.10745T>C p.L3582P | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBF1 | c.3311C>T p.A1104V (on ENST00000586717; = p.A1119V on NM_001319193.1) | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FBXL4 | c.1827C>G p.S609R | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.8633A>G p.Y2878C | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRA5 | c.1024A>G p.N342D | Missense Mutation (SNP) | VAF 97/325 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPD2 | c.1799A>G p.Y600C | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- GPR171 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN2 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HDAC4 | c.2763G>T p.E921D | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- INSRR | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- KIF4B | c.2238G>C p.W746C | Missense Mutation (SNP) | VAF 124/318 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- LRRCC1 | c.2737C>T p.L913F | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MDN1 | c.1786G>C p.V596L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MFSD13A | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGMT | c.666G>T p.W222C (on ENST00000306010; = p.W191C on NM_002412.5) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- MMP17 | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MON1B | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCT1 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NBPF9 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NEURL1 | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NOL8 | c.2881A>G p.R961G | Missense Mutation (SNP) | VAF 114/183 reads (62%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPIPB3 | c.80T>A p.M27K (on ENST00000542817; = p.M243K on NM_130464.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by mutect2, varscan2
- NUP35 | c.643T>G p.Y215D | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTULINL | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- PCNT | c.3732G>A p.M1244I | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PHF14 | c.1417C>G p.Q473E | Missense Mutation (SNP) | VAF 146/320 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PLEKHG2 | c.3988G>A p.A1330T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PMEL | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PPP1R21 | c.2129A>G p.K710R (on ENST00000294952 / NM_001135629.3; = p.K699R on NM_152994.5) | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- PPP4R1 | c.2059A>G p.I687V (on ENST00000400556 / NM_001042388.3; = p.I670V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- RXRG | c.1063G>C p.V355L | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SEMA5B | c.1639G>C p.G547R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SH2D7 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SLFN12L | c.1092T>G p.S364R (on ENST00000260908 / NM_001363830.1; = p.S382R on NM_001195790.1) | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SPIRE2 | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SPTBN2 | c.2878A>T p.I960F | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SRCAP | c.5062G>C p.A1688P | Missense Mutation (SNP) | VAF 83/367 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SRP54 | c.1272dup p.T425Yfs*24 | Frame Shift Ins (INS) | VAF 26/169 reads (15%) | called by mutect2, pindel, varscan2
- TGS1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TIGD7 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- TJP3 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- TMEM88 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- TP53INP1 | c.404A>G p.H135R | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM8 | c.344G>C p.C115S | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.37852C>A p.P12618T (on ENST00000591111; = p.P5194T on NM_003319.4) | Missense Mutation (SNP) | VAF 114/364 reads (31%) | PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZAN | c.6323A>G p.Q2108R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by mutect2, varscan2
- ZGRF1 | c.3127+6C>A | Splice Region (SNP) | VAF 41/155 reads (26%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.1524A>G p.I508M | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C19orf47 | c.657C>T p.T219= | Silent (SNP) | VAF 50/194 reads (26%) | catalogued as COSV63508549; called by muse, mutect2, varscan2
- C1orf216 | c.438A>T p.S146= | Silent (SNP) | VAF 74/245 reads (30%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.534C>G p.L178= | Silent (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
- CCDC88A | c.693A>G p.A231= | Silent (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- CDX2 | c.174G>A p.A58= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs899418379; called by muse, mutect2
- DALRD3 | c.1011T>C p.H337= (on ENST00000341949 / NM_001009996.3; = p.H170= on NM_018114.5) | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1434700175; called by muse, mutect2, varscan2
- DNA2 | c.2073G>A p.K691= | Silent (SNP) | VAF 65/244 reads (27%) | called by muse, mutect2, varscan2
- DNAH2 | c.9702C>T p.L3234= | Silent (SNP) | VAF 63/199 reads (32%) | catalogued as rs145546851; called by muse, mutect2, varscan2
- DNAH7 | c.10995C>A p.P3665= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as COSV56780450; called by muse, mutect2, varscan2
- DST | c.12759A>G p.K4253= (on ENST00000361203 / NM_001374722.1; = p.K1841= on NM_015548.5) | Silent (SNP) | VAF 73/244 reads (30%) | called by muse, mutect2, varscan2
- EBF1 | c.1344C>T p.S448= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs751083175, COSV100565245; called by muse, mutect2, varscan2
- EBLN2 | c.588A>T p.G196= | Silent (SNP) | VAF 83/212 reads (39%) | called by muse, mutect2, varscan2
- GIT2 | c.1056C>T p.D352= (on ENST00000355312 / NM_057169.5; = p.D354= on NM_014776.5) | Silent (SNP) | VAF 62/230 reads (27%) | catalogued as rs750250649, COSV58084229; called by muse, mutect2, varscan2
- HNRNPC | c.483A>T p.V161= (on ENST00000420743; = p.V148= on NM_004500.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/267 reads (23%) | called by muse, mutect2, varscan2
- KRT25 | c.1017G>A p.A339= | Silent (SNP) | VAF 89/331 reads (27%) | catalogued as rs753281617, COSV56443647; called by muse, mutect2, varscan2
- KRT6B | c.219A>T p.G73= | Silent (SNP) | VAF 108/485 reads (22%) | called by muse, mutect2, varscan2
- LEKR1 | c.204G>T p.L68= | Silent (SNP) | VAF 55/240 reads (23%) | catalogued as rs1034317899; called by muse, mutect2, varscan2
- LRP1B | c.1347A>T p.S449= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- MAP1A | c.2394T>A p.S798= | Silent (SNP) | VAF 106/180 reads (59%) | called by muse, mutect2, varscan2
- MYH1 | c.5232G>A p.E1744= | Silent (SNP) | VAF 50/238 reads (21%) | catalogued as rs749841668, COSV56848594; called by muse, mutect2, varscan2
- MYO3A | c.2073C>T p.V691= | Silent (SNP) | VAF 203/438 reads (46%) | catalogued as COSV99779970; called by muse, mutect2, varscan2
- NDST4 | c.912C>T p.I304= | Silent (SNP) | VAF 60/213 reads (28%) | catalogued as COSV52137323; called by muse, mutect2, varscan2
- PDE6C | c.75C>T p.D25= | Silent (SNP) | VAF 89/316 reads (28%) | called by muse, mutect2, varscan2
- PIKFYVE | c.1743T>A p.P581= | Silent (SNP) | VAF 105/351 reads (30%) | called by muse, mutect2, varscan2
- RPS6KA4 | c.1299C>T p.S433= | Silent (SNP) | VAF 97/250 reads (39%) | catalogued as rs747601129, COSV53700756; called by muse, mutect2, varscan2
- SALL1 | c.3927C>T p.F1309= | Silent (SNP) | VAF 65/276 reads (24%) | called by muse, mutect2, varscan2
- SMYD5 | c.63C>G p.V21= | Silent (SNP) | VAF 47/210 reads (22%) | catalogued as COSV50265174; called by muse, mutect2, varscan2
- SRCIN1 | c.2478C>T p.R826= (on ENST00000621492; = p.R792= on NM_025248.3) | Silent (SNP) | VAF 88/299 reads (29%) | catalogued as rs760350456; called by muse, mutect2, varscan2
- TMEM30A | c.282T>C p.C94= | Silent (SNP) | VAF 39/154 reads (25%) | called by muse, mutect2, varscan2
- TMEM33 | c.69G>A p.L23= | Silent (SNP) | VAF 65/211 reads (31%) | called by muse, mutect2, varscan2
- VWA2 | c.1677C>G p.L559= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as COSV53905904; called by muse, mutect2, varscan2
- ZBED6 | c.648A>G p.E216= | Silent (SNP) | VAF 67/305 reads (22%) | called by muse, mutect2, varscan2
- ZNF709 | c.1476G>T p.R492= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV67195550; called by muse, mutect2, varscan2
- C5orf63 | c.171+759C>T | Intron (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- EPM2A | c.301+15C>T | Intron (SNP) | VAF 36/157 reads (23%) | catalogued as rs1445633273; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2463+1112G>A | Intron (SNP) | VAF 26/108 reads (24%) | catalogued as rs1374397821, COSV58544516; called by muse, mutect2, varscan2
- GAR1 | c.429+97dup | Intron (INS) | VAF 39/215 reads (18%) | called by mutect2, pindel, varscan2
- GJC2 | c.*49C>G | 3'UTR (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2
- H4-16 | chr12:14775387 C>T | 5'Flank (SNP) | VAF 57/193 reads (30%) | called by muse, mutect2, varscan2
- MAMLD1 | c.*141A>G | 3'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40545976 G>A | 3'Flank (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- NRXN3 | c.989-7483G>A | Intron (SNP) | VAF 37/132 reads (28%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*2463G>A | 3'UTR (SNP) | VAF 64/384 reads (17%) | called by muse, mutect2, varscan2
- REXO1L1P | n.1479G>T | RNA (SNP) | VAF 99/2082 reads (5%) | called by muse, mutect2
- TMEM161B | chr5:88190136 del AA | 3'Flank (DEL) | VAF 59/174 reads (34%) | called by mutect2, pindel, varscan2
- XKR4 | c.806+58322C>G | Intron (SNP) | VAF 115/248 reads (46%) | called by muse, mutect2, varscan2
- ZNF330 | c.121-688G>A | Intron (SNP) | VAF 34/151 reads (23%) | called by muse, mutect2, varscan2
